Somatic mutation profile of tumor specimen TCGA-EI-6510-01A (aliquot TCGA-EI-6510-01A-11D-1733-10) from TCGA case TCGA-EI-6510, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 77.6 years (28,328 days).
Specimen TCGA-EI-6510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ff8b97b-0dd2-46bf-a4fd-0536899b2619.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6510-10A (Blood Derived Normal), aliquot TCGA-EI-6510-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b4f15f4-7f69-4119-a80f-66a2cf389950

The open-access MAF lists 118 somatic variants for this specimen: 90 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 27, Frame Shift Del 8, Nonsense Mutation 6, Splice Site 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/92 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 9/74 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AC013489.1 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752634307, COSV51552830; called by muse, mutect2, varscan2
- ACTN2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as rs781251434, COSV63976308, COSV63976810; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3949G>A p.V1317M | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs77086705, COSV54438029; called by muse, mutect2, varscan2
- ADGRF5 | c.1912G>T p.V638F | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV51938075; called by muse, mutect2, varscan2
- ANKRD28 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV67519576; called by muse, mutect2, varscan2
- ASCC1 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.205); catalogued as rs1269493311, COSV100192091; called by muse, varscan2
- BTBD1 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs769208205, COSV55604174; called by muse, mutect2, varscan2
- CYTH3 | c.101T>G p.L34R | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100641628; called by muse, mutect2, varscan2
- DAPK3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs967919275, COSV56664079; called by muse, varscan2
- DDC | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as CM077528, COSV63566849; called by muse, mutect2, varscan2
- DNER | c.1012T>A p.C338S | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100520179; called by muse, mutect2
- DOCK1 | c.4357G>C p.E1453Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs777850348, COSV54752791; called by muse, mutect2, varscan2
- EFCAB6 | c.3977G>A p.R1326H | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs749917338, COSV53067194; called by muse, mutect2, varscan2
- ERBB4 | c.2891G>A p.R964K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100728188, COSV61497713; called by muse, mutect2, varscan2
- ESPNL | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as rs781528755, COSV58036045; called by muse, mutect2, varscan2
- FABP12 | c.291C>A p.D97E | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV64617527; called by muse, mutect2, varscan2
- FAT1 | c.3625del p.D1209Mfs*5 | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | catalogued as COSV71675386; called by mutect2, pindel, varscan2
- FSD2 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV58011984; called by muse, mutect2, varscan2
- GALNT17 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as COSV61180809; called by muse, mutect2, varscan2
- GALNT9 | c.1310G>A p.R437H (on ENST00000328957 / NM_001122636.2; = p.R71H on NM_021808.3) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767618128, COSV61101867; called by muse, mutect2, varscan2
- GPLD1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1331636024, COSV57758727, COSV57759871; called by muse, mutect2, varscan2
- GPR50 | c.725T>C p.I242T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99506744; called by muse, mutect2, varscan2
- GREB1 | c.5461C>A p.H1821N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV52193047; called by muse, mutect2, varscan2
- HERC5 | c.2722G>T p.V908L | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV52043029; called by muse, mutect2, varscan2
- HPS3 | c.621A>C p.L207F | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV56056486; called by muse, mutect2
- IGF2BP2 | c.44C>A p.T15N | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.719); catalogued as COSV60489697; called by muse, varscan2
- IQCF1 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV58823835; called by muse, mutect2, varscan2
- IRX1 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1339250871, COSV57361478; called by muse, mutect2, varscan2
- KCNU1 | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1376104188, COSV67758674; called by muse, mutect2, varscan2
- KDM3B | c.1664del p.D555Afs*10 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as COSV58693651; called by mutect2, pindel*, varscan2
- KIF5B | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 137/462 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs141491660; called by muse, mutect2, varscan2
- KLRK1 | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs1255050953, COSV53699502; called by muse, mutect2, varscan2
- LGR4 | c.1996del p.A666Pfs*6 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as COSV60821407; called by mutect2, pindel, varscan2
- LIX1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.431); catalogued as COSV57207855; called by muse, mutect2, varscan2
- LRRIQ1 | c.4175G>A p.R1392Q | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757973024, COSV67829714; called by muse, mutect2, varscan2
- MCTP2 | c.2552C>A p.P851Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63296211; called by muse, mutect2, varscan2
- MOSPD2 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs1221540390, COSV60761196; called by muse, mutect2, varscan2
- NFKB2 | c.2476G>A p.G826R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401571962, COSV50053669; called by muse, mutect2, varscan2
- NOSIP | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100182506; called by muse, mutect2, varscan2
- NOXA1 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769178904, COSV100395747; called by muse, mutect2, varscan2
- NYX | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100699491; called by muse, mutect2, varscan2
- OAS2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs143746502; called by muse, mutect2, varscan2
- OR5AC2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs769617683, COSV62279168; called by muse, mutect2, varscan2
- OR6C75 | c.804A>T p.L268F | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.952); catalogued as COSV58553216; called by muse, mutect2
- PANX2 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs377448993; called by muse, mutect2, varscan2
- PCDHA6 | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65342498; called by muse, mutect2, varscan2
- PCYT1B | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV100770539, COSV63265968; called by muse, mutect2, varscan2
- PDGFD | c.355A>C p.I119L | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1275142720, COSV56385869, COSV56388304; called by muse, mutect2, varscan2
- PLCD3 | c.923A>T p.H308L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.871); catalogued as COSV59562086; called by muse, mutect2, varscan2
- PPP3CC | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs558233561, COSV51502653; called by muse, mutect2, varscan2
- PRG4 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs1177332578, COSV63356162; called by muse, mutect2, varscan2
- RBM10 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as COSV61308434; called by muse, mutect2, varscan2
- RIMBP2 | c.3037T>C p.F1013L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2, varscan2
- RPF2 | c.245C>A p.S82* | Nonsense Mutation (SNP) | VAF 45/148 reads (30%) | catalogued as COSV64370227; called by muse, mutect2, varscan2
- SH3BP5 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53745833; called by muse, mutect2, varscan2
- SHQ1 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 40/236 reads (17%) | catalogued as rs777239706, COSV57765544; called by muse, mutect2, varscan2
- SLC23A1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.544); catalogued as rs753453829, COSV62297314; called by muse, mutect2, varscan2
- SLC30A8 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.087); catalogued as rs778716564, COSV69974396; called by muse, mutect2, varscan2
- SLC9A7 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs375953952, COSV60378801; called by mutect2, varscan2
- SPINK4 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 35/105 reads (33%) | catalogued as COSV65688215; called by muse, mutect2, varscan2
- SYNE1 | c.8374C>T p.R2792C (on ENST00000367255 / NM_182961.4; = p.R2799C on NM_033071.3) | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1249221823, COSV99581133; called by muse, mutect2, varscan2
- SYNE3 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs542033506, COSV62078580; called by muse, mutect2, varscan2
- SYTL1 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV58873731; called by muse, mutect2, varscan2
- TAFA1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.338); catalogued as rs754121777, COSV72037425; called by muse, mutect2, varscan2
- TBC1D8B | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372432035, COSV52175489; called by muse, mutect2, varscan2
- TLR2 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs745621022, COSV52607568; called by muse, mutect2, varscan2
- TNIK | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV52690971, COSV99458893; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs138345857; ClinVar: uncertain significance; called by muse, mutect2
- TRA2B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 121/251 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV52025194; called by muse, mutect2, varscan2
- TSC22D3 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV59778806; called by muse, mutect2, varscan2
- TTN | c.11024G>T p.G3675V (on ENST00000591111; = p.G3629V on NM_003319.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs72648919, COSV60243385; called by muse, mutect2, varscan2
- TYR | c.1459G>T p.V487F | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV54470416, COSV54482612; called by muse, mutect2, varscan2
- UBE2A | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1401369647, COSV60635909; called by muse, mutect2, varscan2
- ULK4 | c.541+1G>A p.X181_splice | Splice Site (SNP) | VAF 24/464 reads (5%) | catalogued as COSV57217870; called by muse, mutect2
- USP34 | c.1377+1G>A p.X459_splice | Splice Site (SNP) | VAF 31/89 reads (35%) | catalogued as COSV68403100; called by muse, mutect2, varscan2
- WWC1 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54656357; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as rs149951499; called by muse, mutect2, varscan2
- ZNF182 | c.1145C>G p.T382S | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as COSV59358820; called by muse, mutect2, varscan2
- ZNF512B | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 26/409 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); catalogued as rs1008446966, COSV53871542; called by muse, mutect2
- ZNF544 | c.1828G>A p.G610R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54137440; called by muse, mutect2, varscan2
- APC | c.688_692del p.R230Tfs*20 | Frame Shift Del (DEL) | VAF 61/127 reads (48%) | called by mutect2, pindel, varscan2
- BAIAP2L1 | c.1378_1395del p.S460_P465del | In Frame Del (DEL) | VAF 23/41 reads (56%) | called by mutect2, pindel, varscan2
- CHRNB3 | c.873del p.V292Sfs*13 | Frame Shift Del (DEL) | VAF 124/386 reads (32%) | called by mutect2, pindel, varscan2
- GABRG2 | c.1426A>G p.I476V (on ENST00000361925 / NM_001375343.1; = p.I436V on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); called by muse, mutect2
- IGFLR1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.118); called by muse, varscan2
- MCHR1 | c.8_9del p.V3Gfs*85 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | called by mutect2, varscan2*
- PRAMEF10 | c.1055del p.K352Rfs*5 | Frame Shift Del (DEL) | VAF 42/197 reads (21%) | called by mutect2, varscan2
- ROCK2 | c.1586del p.L529Wfs*8 | Frame Shift Del (DEL) | VAF 72/239 reads (30%) | called by mutect2, pindel, varscan2
- ATF7IP2 | c.345G>A p.S115= | Silent (SNP) | VAF 64/172 reads (37%) | catalogued as rs746450238, COSV61094790; called by muse, mutect2, varscan2
- BEND7 | c.1128G>A p.A376= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs775281585, COSV61988822; called by muse, mutect2, varscan2
- CHRM5 | c.1410G>A p.K470= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs547672974, COSV67248155; called by muse, mutect2, varscan2
- COL12A1 | c.5466C>T p.T1822= | Silent (SNP) | VAF 29/260 reads (11%) | catalogued as rs373978519, COSV59396988; called by muse, mutect2, varscan2
- DYNC2I1 | c.682C>A p.R228= | Silent (SNP) | VAF 112/183 reads (61%) | catalogued as COSV68103969, COSV68106409; called by muse, mutect2, varscan2
- EPN3 | c.321G>A p.K107= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV52142143; called by muse, mutect2, varscan2
- ERCC4 | c.2307C>T p.L769= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs765321722, COSV61313333; called by muse, mutect2, varscan2
- FAT2 | c.8778G>A p.A2926= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs374640362, COSV55821401; called by muse, mutect2, varscan2
- FLI1 | c.1128G>A p.S376= | Silent (SNP) | VAF 29/184 reads (16%) | catalogued as rs766521149, COSV55646864; called by muse, mutect2, varscan2
- FOXO4 | c.846G>A p.A282= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1449817786, COSV58576102, COSV58576511; called by muse, mutect2, varscan2
- IGF2BP2 | c.45C>G p.T15= | Silent (SNP) | VAF 53/184 reads (29%) | catalogued as COSV60489689; called by muse, varscan2
- IL13RA2 | c.1077C>T p.T359= | Silent (SNP) | VAF 31/312 reads (10%) | catalogued as rs191854615, COSV54565442, COSV99683417; called by muse, mutect2, varscan2
- JPH3 | c.1419C>T p.D473= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs539750381, COSV52469791; called by muse, mutect2
- KLF10 | c.1005C>T p.S335= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs745774507, COSV53435639; called by muse, mutect2, varscan2
- KLHL18 | c.1350C>T p.Y450= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as COSV51747654; called by muse, mutect2, varscan2
- LRRIQ1 | c.273T>C p.N91= | Silent (SNP) | VAF 98/730 reads (13%) | catalogued as rs777995024, COSV101277745; called by muse, mutect2
- MLXIPL | c.1317C>T p.T439= | Silent (SNP) | VAF 66/103 reads (64%) | catalogued as rs912561153, COSV100515577; called by muse, mutect2, varscan2
- PCDHA11 | c.2187C>T p.G729= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as COSV56484702; called by muse, mutect2, varscan2
- PCDHA6 | c.1629G>A p.P543= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV65344271; called by muse, mutect2, varscan2
- PCED1B | c.297C>T p.S99= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101423693; called by muse, mutect2, varscan2
- PI4KA | c.5103C>T p.G1701= | Silent (SNP) | VAF 15/192 reads (8%) | catalogued as COSV55413576; called by muse, mutect2
- SCN3A | c.3357G>A p.E1119= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV99328717; called by muse, mutect2
- SLC5A2 | c.1032G>A p.A344= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1450739929, COSV57893521, COSV57894970; called by muse, mutect2, varscan2
- SOX8 | c.432C>T p.S144= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs755447385, COSV53510264; called by muse, mutect2, varscan2
- SPTB | c.6855C>T p.T2285= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs758573607, COSV55982447, COSV99906297; called by muse, mutect2, varscan2
- TG | c.3543T>C p.C1181= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV99603509; called by muse, mutect2, varscan2
- TRANK1 | c.2430C>T p.V810= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- TTN | c.10361-4571G>T | Intron (SNP) | VAF 78/217 reads (36%) | catalogued as COSV60243395; called by muse, mutect2, varscan2
